Somatic mutation profile of tumor specimen ALCH-B2A4-TTP1-A (aliquot ALCH-B2A4-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2A4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 73.2 years (26,750 days).
Specimen ALCH-B2A4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aaf42613-bbb5-485e-953c-7c940fcd9f6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2A4-NB1-A (Blood Derived Normal), aliquot ALCH-B2A4-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d498f05-b9aa-4378-aa7d-c15b65d6470d

The open-access MAF lists 306 somatic variants for this specimen: 219 protein-altering or splice-affecting, 59 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 59, Nonsense Mutation 21, Intron 13, Frame Shift Del 8, Splice Site 6, RNA 6, 5'UTR 4, 5'Flank 3, 3'UTR 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT9 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 32/277 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1057519956, COSV55299564; ClinVar: likely pathogenic; called by muse, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 78/508 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HK1 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794848; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 39/397 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ORC6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 70/664 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs777153067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72549394, CM980252, COSV55593121; called by muse, mutect2, varscan2
- AC136428.1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 57/455 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV71169188; called by muse, mutect2, varscan2
- ADGRB3 | c.1897G>T p.A633S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as rs921122129; called by muse, mutect2, varscan2
- ANHX | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV69293955; called by muse, mutect2
- ARHGAP5 | c.4363G>A p.V1455I (on ENST00000345122 / NM_001030055.2; = p.V1454I on NM_001173.3) | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1203882701; called by muse, mutect2, varscan2
- BOD1L2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.283); catalogued as COSV101649286; called by muse, mutect2, varscan2
- C2CD3 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs754367795, COSV58090296, COSV58097566; called by muse, mutect2, varscan2
- C8B | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 62/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557740342, COSV64777353; called by muse, mutect2, varscan2
- CACNA2D4 | c.2191G>T p.V731L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV54948398; called by muse, mutect2, varscan2
- CBFA2T3 | c.1616C>G p.S539C | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV51931195; called by muse, mutect2, varscan2
- CCDC39 | c.2735C>T p.P912L | Missense Mutation (SNP) | VAF 44/425 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs760435440; called by muse, mutect2, varscan2
- CEP290 | c.5722G>T p.E1908* | Nonsense Mutation (SNP) | VAF 20/170 reads (12%) | catalogued as CM072937, COSV58355803; called by muse, mutect2, varscan2
- CHP1 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100587019; called by muse, mutect2
- CLEC4C | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63582527; called by muse, mutect2
- CNGB3 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 70/426 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs139207764, CM154647, COSV100181056; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2
- COL1A1 | c.3314G>T p.R1105I | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD063482; called by muse, mutect2, varscan2
- COL6A2 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 48/614 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs727502833, COSV100153766; ClinVar: uncertain significance; called by muse, mutect2
- CP | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.595); catalogued as COSV52832012, COSV52834146; called by muse, mutect2, varscan2
- CSMD2 | c.8434C>T p.R2812C | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1398421781; called by muse, mutect2
- DCAF4L2 | c.59G>T p.R20I | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60479766, COSV60481411; called by muse, mutect2, varscan2
- DCHS1 | c.9757A>T p.S3253C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54998279; called by muse, mutect2
- DLL4 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99989742; called by muse, mutect2, varscan2
- DNAH8 | c.10057G>T p.A3353S | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59444496; called by muse, mutect2
- DUXA | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV73729670; called by muse, mutect2
- FAM171A1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as rs762827738, COSV65317711; called by muse, mutect2, varscan2
- FAM71B | c.331C>A p.R111S | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV57228351; called by muse, mutect2
- FOXD1 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.425); catalogued as rs1192028781, COSV100197732; called by muse, mutect2, varscan2
- FREM3 | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as rs865801281; called by muse, mutect2, varscan2
- GABRB3 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 64/806 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV54659758, COSV54677069; called by muse, mutect2
- GPA33 | c.691+1G>T p.X231_splice | Splice Site (SNP) | VAF 18/196 reads (9%) | catalogued as COSV63300760; called by muse, mutect2
- GRIA1 | c.1160A>C p.K387T | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.134); catalogued as COSV53589598; called by muse, mutect2
- HMMR | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62375180; called by muse, mutect2, varscan2
- IGFALS | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs561329938, COSV51905092; called by muse, mutect2
- IGLV2-14 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 48/536 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); catalogued as rs768131871; called by muse, mutect2
- IL31RA | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 48/473 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV51680542; called by muse, mutect2, varscan2
- KCNH8 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 56/501 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs747108581; called by muse, mutect2, varscan2
- KEAP1 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50261740; called by muse, mutect2, varscan2
- LILRB1 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 46/433 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV61121187; called by muse, mutect2, varscan2
- MALRD1 | c.3307C>G p.P1103A | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as COSV101039633; called by muse, mutect2, varscan2
- MAP7D3 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as rs1312380475; called by muse, mutect2, varscan2
- MROH2A | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.588); catalogued as rs1287521749; called by muse, mutect2, varscan2
- MROH7 | c.461A>T p.K154M | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.178); catalogued as rs375822785; called by muse, mutect2, varscan2
- NPAP1 | c.2959G>T p.G987W | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV100274795; called by muse, mutect2
- NR4A1 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.21); catalogued as COSV54482935; called by muse, mutect2
- NRCAM | c.385C>A p.R129S (on ENST00000379028 / NM_001371124.1; = p.R123S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.664); catalogued as COSV61044271; called by muse, mutect2, varscan2
- NUP153 | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs778385534; called by muse, mutect2, varscan2
- OR4C15 | c.671C>T p.P224L (on ENST00000314644; = p.P170L on NM_001001920.2) | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs756094344, COSV58953119; called by muse, mutect2
- PAQR6 | c.553del p.R185Afs*35 (on ENST00000292291 / NM_001272108.2; = p.R79Afs*35 on NM_024897.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 76/460 reads (17%) | catalogued as rs763189895, COSV99430646; called by mutect2, pindel, varscan2
- PEG3 | c.1743C>G p.H581Q | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771837389; called by muse, mutect2, varscan2
- PF4V1 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV104389561; called by muse, mutect2, varscan2
- PJA1 | c.1301del p.G434Afs*50 (on ENST00000361478 / NM_145119.4; = p.G246Afs*50 on NM_022368.5) | Frame Shift Del (DEL) | VAF 34/180 reads (19%) | catalogued as COSV64053553; called by mutect2, pindel*, varscan2
- PLCL1 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 24/336 reads (7%) | catalogued as COSV70820741; called by muse, mutect2
- POSTN | c.1465del p.R489Afs*15 | Frame Shift Del (DEL) | VAF 47/403 reads (12%) | catalogued as COSV65712393; called by mutect2, pindel, varscan2
- SIGLEC14 | c.587C>A p.S196* | Nonsense Mutation (SNP) | VAF 29/219 reads (13%) | catalogued as rs1474872460, COSV55778812; called by muse, mutect2, varscan2
- SLC17A6 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99581952; called by muse, mutect2
- SMARCA4 | c.1636A>T p.K546* | Nonsense Mutation (SNP) | VAF 91/797 reads (11%) | catalogued as CD122496; called by muse, mutect2, varscan2
- SMC4 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as COSV61006216; called by muse, mutect2
- SYNPO2L | c.1817C>T p.P606L (on ENST00000394810 / NM_001114133.3; = p.P382L on NM_024875.5) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1179894795, COSV65736656; called by muse, mutect2
- THEMIS | c.1697C>G p.T566R | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64072673; called by muse, varscan2
- TNR | c.4058G>A p.R1353Q | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs779239538, COSV54904244; called by muse, mutect2, varscan2
- UGT2B28 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV59432192; called by muse, mutect2
- XIRP2 | c.8753G>T p.R2918L (on ENST00000628543; = p.R3093L on NM_152381.6) | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV54679955; called by muse, mutect2, varscan2
- ZNF292 | c.2506G>T p.E836* | Nonsense Mutation (SNP) | VAF 28/378 reads (7%) | catalogued as COSV60544633; called by muse, mutect2
- ACCS | c.806T>A p.L269Q | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAD1 | c.417C>A p.Y139* | Nonsense Mutation (SNP) | VAF 19/212 reads (9%) | called by muse, mutect2
- ADAM33 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM33 | c.1771G>C p.V591L | Missense Mutation (SNP) | VAF 62/610 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- ADAMTS2 | c.912C>A p.D304E | Missense Mutation (SNP) | VAF 44/546 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- ADD2 | c.744C>A p.H248Q | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADGRL3 | c.3157C>G p.L1053V (on ENST00000506720 / NM_001322402.2; = p.L985V on NM_015236.6) | Missense Mutation (SNP) | VAF 54/562 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.163); called by muse, mutect2
- ADGRL3 | c.3823G>A p.A1275T | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ADGRV1 | c.3965A>G p.H1322R | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ALDOC | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 55/479 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ATP6V0A1 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- BCL11B | c.2472C>A p.Y824* (on ENST00000357195 / NM_001282237.2; = p.Y753* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 102/707 reads (14%) | called by muse, mutect2, varscan2
- BOD1L1 | c.5378G>T p.S1793I | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C11orf53 | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2
- C14orf39 | c.1348C>G p.P450A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C8orf34 | c.1226G>A p.C409Y | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1C | c.6581C>A p.P2194Q (on ENST00000399634 / NM_001167625.1; = p.P2123Q on NM_000719.7) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2
- CACNA1I | c.5066G>T p.R1689L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CACNG6 | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- CADM2 | c.654G>C p.M218I (on ENST00000407528 / NM_001167674.2; = p.M220I on NM_153184.4) | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- CALCR | c.347del p.G116Vfs*27 | Frame Shift Del (DEL) | VAF 20/204 reads (10%) | called by mutect2, pindel, varscan2
- CCDC168 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CCNB3 | c.3530T>C p.M1177T | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CNTN1 | c.2203C>A p.H735N | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.796); called by muse, mutect2
- CPPED1 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRB1 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 44/475 reads (9%) | called by muse, mutect2
- CSPG5 | c.1659G>C p.Q553H (on ENST00000383738 / NM_001206943.2; = p.Q526H on NM_006574.4) | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CUBN | c.9604A>T p.N3202Y | Missense Mutation (SNP) | VAF 44/433 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- DCTN5 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- DNMT3A | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2
- DRC1 | c.779A>T p.N260I | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- EMSY | c.2597A>T p.Q866L | Missense Mutation (SNP) | VAF 54/415 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ETFB | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 72/657 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- FAM98A | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.6920C>A p.S2307Y | Missense Mutation (SNP) | VAF 89/748 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FSIP2 | c.19528C>G p.Q6510E | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- GHR | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 56/680 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2
- GJD2 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2
- GPR158 | c.1828C>G p.P610A | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUCY1A1 | c.826del p.V276* | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- HAS2 | c.1524dup p.Q509Tfs*28 | Frame Shift Ins (INS) | VAF 32/261 reads (12%) | called by mutect2, pindel, varscan2
- IFI44L | c.695G>C p.G232A | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGFBP5 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KCMF1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- KMT2B | c.2862_2866del p.H956Rfs*37 | Frame Shift Del (DEL) | VAF 41/357 reads (11%) | called by mutect2, pindel, varscan2
- KRT35 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 62/609 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2
- KRTAP10-3 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 99/924 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA2 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 53/518 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDLRAD1 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LHX8 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LRFN5 | c.562A>T p.K188* | Nonsense Mutation (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- LRRCC1 | c.543A>T p.P181= | Splice Region (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- LUZP4 | c.153del p.R51Sfs*56 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel, varscan2
- MAGEB5 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP2K1 | c.517-1G>T p.X173_splice | Splice Site (SNP) | VAF 45/447 reads (10%) | called by muse, mutect2, varscan2
- MAP3K9 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- MICAL3 | c.4399G>T p.E1467* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2
- MLLT6 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 63/638 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPPED2 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTHFD2 | c.992T>A p.V331E | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.222); called by muse, mutect2
- MTUS2 | c.2291T>A p.M764K | Missense Mutation (SNP) | VAF 60/604 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- MUC2 | c.2750C>A p.S917Y | Missense Mutation (SNP) | VAF 35/354 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MUC5B | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- MYBL2 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
- MYBPC1 | c.3171T>G p.Y1057* (on ENST00000550270 / NM_206820.2; = p.Y1064* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 32/412 reads (8%) | called by muse, mutect2
- MYH2 | c.4390C>T p.Q1464* | Nonsense Mutation (SNP) | VAF 39/357 reads (11%) | called by muse, mutect2, varscan2
- NEDD4 | c.3890C>T p.S1297L (on ENST00000508342 / NM_001284338.1; = p.S878L on NM_006154.4) | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- NFKB1 | c.1242T>A p.Y414* (on ENST00000394820 / NM_001382627.1; = p.Y415* on NM_003998.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- NLRP7 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 58/511 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP133 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OR2H2 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- OR2L3 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 63/588 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- OR6B2 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 37/621 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2
- PATJ | c.3935C>G p.S1312* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2
- PCDHA1 | c.2188G>T p.G730C | Missense Mutation (SNP) | VAF 40/415 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2
- PCDHGA6 | c.1785_1786del p.D595Efs*170 | Frame Shift Del (DEL) | VAF 64/658 reads (10%) | called by mutect2, pindel, varscan2
- PCLO | c.14368A>T p.T4790S | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- PDP2 | c.1005G>T p.E335D | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF3 | c.1893G>T p.Q631H | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCB4 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PLCL1 | c.554G>T p.C185F | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- PLEKHO1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- PNMA8B | c.224A>T p.H75L | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PNPLA5 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- POLE | c.1991A>T p.Q664L | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- PPFIBP1 | c.1998T>A p.N666K (on ENST00000318304 / NM_177444.3; = p.N660K on NM_003622.4) | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.297); called by muse, mutect2
- PPFIBP1 | c.1999T>A p.S667T (on ENST00000318304 / NM_177444.3; = p.S661T on NM_003622.4) | Missense Mutation (SNP) | VAF 25/363 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.059); called by muse, mutect2
- PPP1R16B | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PPP1R26 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PRAMEF15 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 16/608 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PRR36 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated, low confidence (0.69); called by muse, mutect2, varscan2
- PSMB11 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 34/282 reads (12%) | called by muse, mutect2, varscan2
- PSMD13 | c.464T>A p.F155Y | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2
- PTH2R | c.1363G>T p.V455L | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTK2 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- PTPRN2 | c.3013G>T p.E1005* | Nonsense Mutation (SNP) | VAF 24/416 reads (6%) | called by muse, mutect2
- QSOX1 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RELN | c.3144C>A p.C1048* | Nonsense Mutation (SNP) | VAF 49/577 reads (8%) | called by muse, mutect2
- RESP18 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RNF17 | c.4545T>A p.F1515L | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RTKN | c.590G>T p.G197V (on ENST00000272430 / NM_001015055.2; = p.G184V on NM_033046.2) | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SCN3A | c.2848G>T p.D950Y | Missense Mutation (SNP) | VAF 71/800 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHANK3 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHISAL1 | c.230A>T p.Q77L | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SIN3A | c.1634A>T p.E545V | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC13A1 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- SLC35G3 | c.125T>G p.V42G | Missense Mutation (SNP) | VAF 42/530 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- SLC6A16 | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.077); called by muse, mutect2
- SLC7A10 | c.660C>A p.S220R | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMG9 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 58/574 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.156); called by muse, mutect2
- SNAP25 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- SPANXN2 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPRED1 | c.163T>A p.C55S | Missense Mutation (SNP) | VAF 63/570 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB2 | c.1735G>T p.G579* | Nonsense Mutation (SNP) | VAF 43/332 reads (13%) | called by muse, mutect2, varscan2
- STIM2 | c.1958G>T p.C653F | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- STXBP2 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 74/519 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STXBP2 | c.664-2A>T p.X222_splice | Splice Site (SNP) | VAF 37/346 reads (11%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1181G>T p.R394M | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SYT16 | c.1802T>A p.M601K | Missense Mutation (SNP) | VAF 53/490 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SYT9 | c.1293C>A p.N431K | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- TAF1L | c.4978C>A p.P1660T | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.993); called by muse, varscan2
- THBS2 | c.2140C>A p.H714N | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TLR10 | c.620T>G p.L207W | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TMEM200A | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); called by muse, mutect2
- TMEM59 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.703); called by muse, mutect2
- TPP1 | c.1532A>G p.H511R | Missense Mutation (SNP) | VAF 64/549 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV22 | c.52+1G>T p.X18_splice | Splice Site (SNP) | VAF 30/228 reads (13%) | called by muse, varscan2
- TRGJP | c.44C>G p.T15R | Missense Mutation (SNP) | VAF 25/259 reads (10%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM21 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 44/397 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TTN | c.5588G>C p.R1863T (on ENST00000591111; = p.R1817T on NM_003319.4) | Missense Mutation (SNP) | VAF 48/471 reads (10%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBR5 | c.8126A>T p.Q2709L | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2
- UGT1A10 | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UNC80 | c.3686T>C p.V1229A | Missense Mutation (SNP) | VAF 43/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- UQCRC2 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- VCAM1 | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 66/465 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- VWC2L | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 48/512 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- WDR72 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- XIRP2 | c.5572G>C p.E1858Q (on ENST00000628543; = p.E2033Q on NM_152381.6) | Missense Mutation (SNP) | VAF 39/392 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- XIRP2 | c.8752C>A p.R2918S (on ENST00000628543; = p.R3093S on NM_152381.6) | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- XPR1 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 86/825 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- YME1L1 | c.1583-2A>T p.X528_splice (on ENST00000326799 / NM_139312.3; = p.X471_splice on NM_014263.4) | Splice Site (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2
- ZCCHC8 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 42/556 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- ZEB2 | c.2824G>T p.G942* | Nonsense Mutation (SNP) | VAF 40/403 reads (10%) | called by muse, mutect2
- ZFPM2 | c.3074C>A p.A1025D | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF180 | c.892G>T p.G298* | Nonsense Mutation (SNP) | VAF 25/278 reads (9%) | called by muse, mutect2
- ZNF337 | c.563A>T p.D188V | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.035); called by muse, mutect2
- ZNF395 | c.1233+1_1233+17del p.X411_splice | Splice Site (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- ZNF714 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, varscan2
- ZNF749 | c.791A>T p.K264M | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); called by muse, mutect2
- ZPBP2 | c.710C>A p.A237E (on ENST00000348931 / NM_199321.3; = p.A215E on NM_198844.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZZEF1 | c.4055A>G p.Y1352C | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ADAMTS20 | c.5625C>T p.V1875= | Silent (SNP) | VAF 27/211 reads (13%) | called by muse, mutect2, varscan2
- ADCY8 | c.2355G>T p.R785= | Silent (SNP) | VAF 48/522 reads (9%) | called by muse, mutect2
- ANK2 | c.2112G>A p.Q704= | Silent (SNP) | VAF 58/600 reads (10%) | catalogued as rs998176656; called by muse, varscan2
- APBB1 | c.1860G>T p.T620= | Silent (SNP) | VAF 40/480 reads (8%) | called by muse, mutect2
- B3GAT1 | c.324G>A p.T108= | Silent (SNP) | VAF 56/608 reads (9%) | catalogued as rs759514133, COSV100438252; called by muse, mutect2
- BEST3 | c.1044A>T p.T348= | Silent (SNP) | VAF 42/391 reads (11%) | catalogued as rs750334856; called by muse, mutect2, varscan2
- CABP1 | c.1017G>T p.V339= (on ENST00000316803 / NM_001033677.1; = p.V136= on NM_004276.5) | Silent (SNP) | VAF 40/324 reads (12%) | called by muse, mutect2, varscan2
- CALCRL | c.483C>A p.G161= | Silent (SNP) | VAF 21/193 reads (11%) | catalogued as rs539464823; called by muse, varscan2
- CARS2 | c.474A>T p.P158= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- CDH23 | c.3381G>T p.T1127= | Silent (SNP) | VAF 83/745 reads (11%) | catalogued as rs752407400; called by muse, mutect2, varscan2
- CDH6 | c.1971C>A p.V657= | Silent (SNP) | VAF 33/306 reads (11%) | called by muse, mutect2, varscan2
- CHP1 | c.102G>T p.R34= | Silent (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- CHST3 | c.486C>T p.F162= | Silent (SNP) | VAF 109/1007 reads (11%) | catalogued as rs774188997, COSV64150708; called by muse, mutect2, varscan2
- CNGB3 | c.465C>T p.L155= | Silent (SNP) | VAF 75/435 reads (17%) | called by muse, mutect2
- CPNE7 | c.1167C>T p.F389= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as rs1166853483; called by muse, mutect2, varscan2
- CPPED1 | c.402C>A p.P134= | Silent (SNP) | VAF 38/474 reads (8%) | catalogued as rs1405736375; called by muse, mutect2
- CSMD3 | c.7182G>A p.V2394= (on ENST00000297405 / NM_001363185.1; = p.V2290= on NM_052900.3) | Silent (SNP) | VAF 40/560 reads (7%) | catalogued as rs1234133046; called by muse, mutect2
- DLG2 | c.2595C>A p.P865= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV54688290; called by muse, mutect2, varscan2
- FN1 | c.4602T>C p.I1534= | Silent (SNP) | VAF 39/307 reads (13%) | called by muse, mutect2, varscan2
- GRM5 | c.1569C>A p.I523= | Silent (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- HS3ST4 | c.171C>A p.G57= | Silent (SNP) | VAF 45/347 reads (13%) | called by muse, mutect2, varscan2
- IGFBP5 | c.54C>A p.A18= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- JMY | c.528G>A p.Q176= | Silent (SNP) | VAF 36/245 reads (15%) | catalogued as rs545856759; called by muse, mutect2, varscan2
- KCNH3 | c.2314C>A p.R772= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- KCNQ5 | c.1533G>T p.V511= | Silent (SNP) | VAF 19/336 reads (6%) | called by muse, mutect2
- KDM5A | c.3177G>A p.R1059= | Silent (SNP) | VAF 74/566 reads (13%) | called by muse, mutect2, varscan2
- KRTAP10-10 | c.258C>A p.T86= | Silent (SNP) | VAF 62/670 reads (9%) | called by muse, mutect2
- KRTAP21-2 | c.174A>G p.G58= | Silent (SNP) | VAF 52/484 reads (11%) | called by muse, mutect2, varscan2
- LIPM | c.480T>A p.A160= | Silent (SNP) | VAF 30/284 reads (11%) | called by muse, mutect2, varscan2
- MAGEB2 | c.351G>A p.S117= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as rs944047855; called by muse, mutect2, varscan2
- MAGI2 | c.804C>A p.P268= | Silent (SNP) | VAF 40/426 reads (9%) | called by muse, mutect2
- MALRD1 | c.5199A>T p.T1733= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as rs1432108231; called by muse, mutect2, varscan2
- MMEL1 | c.207G>A p.R69= | Silent (SNP) | VAF 40/366 reads (11%) | called by muse, mutect2, varscan2
- MSX1 | c.465G>T p.P155= | Silent (SNP) | VAF 25/259 reads (10%) | catalogued as rs768687042; called by muse, mutect2
- MUC16 | c.37698C>A p.S12566= | Silent (SNP) | VAF 32/268 reads (12%) | called by muse, mutect2, varscan2
- MXRA5 | c.1327C>A p.R443= | Silent (SNP) | VAF 28/178 reads (16%) | catalogued as COSV54245869; called by muse, mutect2, varscan2
- MYO15B | c.3393G>T p.R1131= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV73865074; called by muse, mutect2, varscan2
- NCSTN | c.1321C>T p.L441= | Silent (SNP) | VAF 13/458 reads (3%) | called by muse, mutect2
- NIPA1 | c.495G>T p.L165= | Silent (SNP) | VAF 46/508 reads (9%) | called by muse, mutect2
- OBSL1 | c.339C>T p.P113= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- OR10G9 | c.435C>A p.T145= | Silent (SNP) | VAF 40/348 reads (11%) | called by muse, mutect2, varscan2
- OR2T2 | c.102C>A p.S34= | Silent (SNP) | VAF 188/1702 reads (11%) | catalogued as COSV61618736; called by muse, mutect2, varscan2
- PFKFB1 | c.1269C>T p.L423= | Silent (SNP) | VAF 44/276 reads (16%) | called by muse, mutect2, varscan2
- PPARGC1B | c.2019C>T p.A673= | Silent (SNP) | VAF 28/230 reads (12%) | called by muse, mutect2, varscan2
- PRMT7 | c.645C>T p.D215= | Silent (SNP) | VAF 73/662 reads (11%) | catalogued as rs370445147; called by muse, mutect2
- PRMT7 | c.1722C>G p.L574= | Silent (SNP) | VAF 22/211 reads (10%) | called by muse, mutect2, varscan2
- RAD50 | c.855T>C p.D285= | Silent (SNP) | VAF 53/363 reads (15%) | catalogued as rs1357279835; called by muse, mutect2, varscan2
- RYR2 | c.11031A>G p.T3677= | Silent (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- SLC6A20 | c.84G>T p.V28= | Silent (SNP) | VAF 41/439 reads (9%) | catalogued as COSV100653999; called by muse, mutect2
- SLCO5A1 | c.960T>C p.G320= | Silent (SNP) | VAF 25/332 reads (8%) | called by muse, mutect2
- TAF1L | c.4917A>T p.T1639= | Silent (SNP) | VAF 45/351 reads (13%) | catalogued as rs142290416, COSV54256708; called by muse, varscan2
- TET1 | c.6090C>T p.T2030= | Silent (SNP) | VAF 26/253 reads (10%) | called by muse, mutect2, varscan2
- TMED3 | c.537C>A p.V179= | Silent (SNP) | VAF 34/348 reads (10%) | called by muse, mutect2
- TNR | c.4057C>A p.R1353= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV54914158; called by muse, mutect2, varscan2
- TRABD2B | c.570G>C p.L190= | Silent (SNP) | VAF 52/493 reads (11%) | called by muse, mutect2, varscan2
- TRPC3 | c.360C>A p.A120= (on ENST00000379645 / NM_001366479.2; = p.A47= on NM_003305.2) | Silent (SNP) | VAF 24/296 reads (8%) | catalogued as COSV53381882, COSV99312218; called by muse, mutect2
- VWA2 | c.1078C>T p.L360= | Silent (SNP) | VAF 58/328 reads (18%) | called by muse, mutect2, varscan2
- ZNRF1 | c.382C>T p.L128= | Silent (SNP) | VAF 84/670 reads (13%) | catalogued as rs1240869791, COSV57727957; called by muse, mutect2, varscan2
- ZSCAN23 | c.822G>A p.E274= | Silent (SNP) | VAF 26/253 reads (10%) | catalogued as COSV57043716; called by muse, mutect2
- ANO4 | c.-52C>T | 5'UTR (SNP) | VAF 25/341 reads (7%) | called by muse, mutect2
- CBLB | c.2297-44G>T | Intron (SNP) | VAF 45/291 reads (15%) | called by muse, mutect2, varscan2
- CEP126 | c.507-1639C>G | Intron (SNP) | VAF 43/378 reads (11%) | called by muse, mutect2, varscan2
- CLEC7A | c.492+175G>T | Intron (SNP) | VAF 29/322 reads (9%) | called by muse, mutect2
- CLEC7A | c.492+174G>T | Intron (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2
- DNM1P47 | n.539C>G | RNA (SNP) | VAF 24/329 reads (7%) | called by muse, mutect2
- DNM1P47 | n.592A>T | RNA (SNP) | VAF 48/616 reads (8%) | called by muse, mutect2
- GOLPH3L | c.183+499G>A | Intron (SNP) | VAF 12/93 reads (13%) | catalogued as rs1282907634; called by muse, mutect2, varscan2
- HNRNPA3P1 | n.340G>T | RNA (SNP) | VAF 24/190 reads (13%) | called by muse, mutect2, varscan2
- HTR2A | c.-485C>A | 5'UTR (SNP) | VAF 22/286 reads (8%) | catalogued as rs1269787834; called by muse, mutect2
- IGFN1 | c.1242-1681C>A | Intron (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- LMF1 | chr16:975830 C>A | 5'Flank (SNP) | VAF 57/380 reads (15%) | catalogued as rs1446890616; called by muse, mutect2, varscan2
- LYSMD3 | c.-93G>T | 5'UTR (SNP) | VAF 56/548 reads (10%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85434G>C | Intron (SNP) | VAF 66/602 reads (11%) | catalogued as COSV72279811; called by muse, varscan2
- MMP26 | c.-145+92803C>G | Intron (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- OR3A4P | n.492C>T | RNA (SNP) | VAF 32/283 reads (11%) | catalogued as rs1167836825; called by muse, mutect2, varscan2
- OR3A4P | n.952G>T | RNA (SNP) | VAF 46/455 reads (10%) | called by muse, mutect2
- PEG10 | c.*772A>T | 3'UTR (SNP) | VAF 56/436 reads (13%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*265C>T | 3'UTR (SNP) | VAF 41/327 reads (13%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5800C>T | Intron (SNP) | VAF 57/514 reads (11%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159852 G>T | 5'Flank (SNP) | VAF 27/232 reads (12%) | called by muse, mutect2, varscan2
- RPS13 | c.23+68G>T | Intron (SNP) | VAF 23/217 reads (11%) | catalogued as rs966349132; called by muse, mutect2, varscan2
- RUFY2 | c.-223G>C | 5'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- SCN3A | c.3967-32G>T | Intron (SNP) | VAF 36/390 reads (9%) | catalogued as rs755657861; called by muse, mutect2
- SOX8 | chr16:976897 C>T | 5'Flank (SNP) | VAF 54/574 reads (9%) | called by muse, mutect2
- SPEF2 | c.4448-3622C>A | Intron (SNP) | VAF 17/228 reads (7%) | called by muse, mutect2
- UBBP4 | n.881G>A | RNA (SNP) | VAF 36/494 reads (7%) | catalogued as rs763745114; called by muse, mutect2
- ZNF680 | c.254-4003G>T | Intron (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
